Somatic mutation profile of tumor specimen 314de592-f356-4801-8ace-278173 (aliquot 314de592-f356-4801-8ace-278173_D6_1) from CPTAC case 11BR032, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 49.5 years (18,067 days).
Specimen 314de592-f356-4801-8ace-278173: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ba57b6e-f28d-40a5-9065-347f28a8a2c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 560627f2-6763-475a-8c1d-009ef9 (Blood Derived Normal), aliquot 560627f2-6763-475a-8c1d-009ef9_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64f866d8-0c3c-46c9-8710-67b8a8b68c40

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, Splice Site 2, Frame Shift Del 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 44/230 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.210-1G>C p.X70_splice | Splice Site (SNP) | VAF 33/182 reads (18%) | hotspot (GDC flag); catalogued as rs1114167621, CS002683, COSV64288901, COSV64300623, COSV64300922; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NPPC | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1274724785, COSV54945759; called by muse, mutect2, varscan2
- OR5T1 | c.420C>A p.N140K | Missense Mutation (SNP) | VAF 76/325 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV57304840; called by mutect2, varscan2
- PLK3 | c.1913G>T p.R638L | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as COSV59501476; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4372_4390del p.E1458Kfs*41 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- BEGAIN | c.1379C>A p.A460D | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- CCDC190 | c.462A>C p.Q154H | Missense Mutation (SNP) | VAF 17/365 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2
- CEP128 | c.2570C>G p.P857R | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- ITIH6 | c.2752A>G p.T918A | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYG1 | c.947+2T>A p.X316_splice | Splice Site (SNP) | VAF 19/149 reads (13%) | called by muse, mutect2, varscan2
- NLRC3 | c.1283C>G p.A428G | Missense Mutation (SNP) | VAF 16/483 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.058); called by muse, mutect2
- SETX | c.5930T>G p.L1977R | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRINP3 | c.1380C>T p.C460= | Silent (SNP) | VAF 65/398 reads (16%) | catalogued as rs1348043617, COSV66526179; called by muse, mutect2, varscan2
- CMAS | c.1134A>G p.E378= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- ICE1 | c.3711A>G p.E1237= | Silent (SNP) | VAF 47/228 reads (21%) | called by muse, mutect2, varscan2
- IQGAP1 | c.3885C>T p.I1295= | Silent (SNP) | VAF 16/102 reads (16%) | called by mutect2, varscan2
- PCSK5 | c.2655C>T p.C885= | Silent (SNP) | VAF 26/204 reads (13%) | catalogued as rs566244504, COSV101377692; called by muse, mutect2, varscan2
- TUBGCP2 | c.66A>G p.G22= | Silent (SNP) | VAF 52/282 reads (18%) | called by mutect2, varscan2
- FDX2 | c.-7T>A | 5'UTR (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- NT5C2 | c.539+198C>G | Intron (SNP) | VAF 22/159 reads (14%) | called by muse, mutect2, varscan2
